Somatic mutation profile of tumor specimen TCGA-CV-7099-01A (aliquot TCGA-CV-7099-01A-41D-2012-08) from TCGA case TCGA-CV-7099, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 85.2 years (31,134 days).
Specimen TCGA-CV-7099-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9eed0fba-57d4-4979-8a9a-1a5d86f3daa8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7099-10A (Blood Derived Normal), aliquot TCGA-CV-7099-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b999d1f-2334-487c-9400-94c8addd32c4

The open-access MAF lists 298 somatic variants for this specimen: 220 protein-altering or splice-affecting, 76 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 181, Silent 76, Nonsense Mutation 25, Frame Shift Del 7, Frame Shift Ins 3, Splice Site 2, In Frame Del 1, Splice Region 1, RNA 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.655T>C p.F219L | Missense Mutation (SNP) | VAF 27/118 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV57246260, COSV99918190; called by muse, mutect2, varscan2
- NFE2L2 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519922, COSV67959999, COSV67960008, COSV67960140; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- TP53 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 14/37 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs112431538, CM123560, CM995136, COSV52661732, COSV52670664, COSV53234441, COSV53650254; ClinVar: drug response / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.7728A>T p.L2576F | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.117); catalogued as rs1222122798, COSV71288654; called by muse, mutect2, varscan2
- AC008397.2 | c.1554G>C p.K518N | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99442455; called by muse, mutect2, varscan2
- AC013489.1 | c.1192C>T p.R398C | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.417); catalogued as rs762741356, COSV51554828; called by muse, mutect2, varscan2
- ACAD10 | c.2161G>C p.E721Q | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs773927736, COSV100564795; called by muse, mutect2, varscan2
- ADAMTS16 | c.2656G>A p.G886R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs762566566, COSV99943595; called by muse, mutect2, varscan2
- ADGRE1 | c.1402G>C p.E468Q | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT tolerated (0.37); PolyPhen benign (0.165); catalogued as COSV51674788, COSV99166046; called by muse, mutect2, varscan2
- ADGRF4 | c.368G>A p.R123Q | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as rs772794418, COSV51949756; called by muse, mutect2, varscan2
- ADGRV1 | c.11448G>C p.L3816F | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.645); catalogued as COSV67995457; called by muse, mutect2, varscan2
- AJUBA | c.1267C>T p.H423Y | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99401263; called by muse, mutect2, varscan2
- ALDH1L1 | c.740C>G p.S247* | Nonsense Mutation (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99857721; called by muse, mutect2, varscan2
- ALMS1 | c.2398A>G p.K800E | Missense Mutation (SNP) | VAF 53/179 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.168); catalogued as COSV100044213; called by muse, mutect2, varscan2
- AP4B1 | c.670C>T p.R224C | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs138216814; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARNTL | c.1307C>T p.S436L (on ENST00000403290 / NM_001297719.2; = p.S435L on NM_001178.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100724930; called by muse, mutect2, varscan2
- ATP1A3 | c.1343G>A p.R448K (on ENST00000545399 / NM_001256214.2; = p.R435K on NM_152296.5) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.071); catalogued as COSV100132656; called by muse, mutect2, varscan2
- ATP6V1D | c.279G>C p.K93N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV99371027; called by muse, mutect2, varscan2
- ATP8A1 | c.1312G>C p.E438Q | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.53); catalogued as COSV100047592; called by muse, mutect2, varscan2
- ATXN3 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.385); catalogued as COSV100515674; called by muse, mutect2, varscan2
- AZIN1 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.062); catalogued as rs142265787; called by muse, mutect2, varscan2
- BAMBI | c.543G>C p.K181N | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.617); catalogued as COSV100977557, COSV65002993; called by muse, mutect2, varscan2
- BMP2K | c.970C>G p.P324A | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV100622088; called by muse, mutect2, varscan2
- BRCA1 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); catalogued as CM126467, COSV100525361; called by muse, mutect2
- BRWD3 | c.1894G>A p.E632K | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV64752867; called by muse, mutect2, varscan2
- BTBD8 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.638); catalogued as COSV100730514; called by muse, mutect2, varscan2
- C1QTNF1 | c.660C>G p.I220M | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as COSV100190361; called by muse, mutect2, varscan2
- C2orf16 | c.5460G>C p.R1820S | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV100821144; called by muse, mutect2, varscan2
- CABP4 | c.352C>T p.R118* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs1426615876, COSV100351721; called by muse, mutect2, varscan2
- CACNA1F | c.4293+1G>T p.X1431_splice | Splice Site (SNP) | VAF 9/44 reads (20%) | catalogued as COSV100545534; called by muse, mutect2, varscan2
- CAND1 | c.3499G>C p.E1167Q | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101607365; called by muse, mutect2, varscan2
- CASKIN1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs1360236977, COSV100624520; called by muse, mutect2, varscan2
- CASP8 | c.1393C>T p.Q465* (on ENST00000432109 / NM_033355.3; = p.Q482* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 10/30 reads (33%) | catalogued as COSV51844901; called by muse, mutect2, varscan2
- CCDC27 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV53903016, COSV99623094; called by muse, mutect2, varscan2
- CCDC30 | c.1219G>C p.E407Q (on ENST00000340612; = p.E364Q on NM_001080850.3) | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as COSV100501777; called by muse, mutect2, varscan2
- CD19 | c.617C>G p.S206C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.634); catalogued as COSV100218319; called by muse, mutect2, varscan2
- CD96 | c.826G>A p.E276K (on ENST00000283285 / NM_198196.3; = p.E260K on NM_005816.5) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs760533700, COSV99343770; called by muse, mutect2, varscan2
- CDH24 | c.1630G>C p.D544H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99944410; called by muse, mutect2, varscan2
- CHD4 | c.1127C>T p.P376L (on ENST00000357008 / NM_001363606.2; = p.P389L on NM_001273.5) | Missense Mutation (SNP) | VAF 15/117 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV100539583; called by muse, mutect2, varscan2
- CIC | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.026); catalogued as COSV99360500; called by muse, mutect2
- CLHC1 | c.1573G>C p.E525Q | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV101284957; called by muse, mutect2, varscan2
- CNBD2 | c.817G>C p.D273H | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100839203; called by muse, mutect2, varscan2
- CNGB3 | c.1585G>C p.D529H | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100183382, COSV60685347; called by muse, mutect2, varscan2
- CNNM3 | c.1057G>C p.E353Q | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV100562820; called by muse, mutect2, varscan2
- COL25A1 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 46/142 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV101211732; called by muse, mutect2, varscan2
- COL4A5 | c.4140C>G p.I1380M | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV100090744, COSV60372506; called by muse, mutect2, varscan2
- COLEC12 | c.1073G>A p.R358Q | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs140999458; called by muse, varscan2
- CRYBA1 | c.588_591del p.R196Sfs*21 | Frame Shift Del (DEL) | VAF 22/95 reads (23%) | catalogued as rs786205628; called by mutect2, pindel, varscan2
- CST1 | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); catalogued as COSV100494436, COSV59054967, COSV59056403; called by muse, mutect2
- CTNNAL1 | c.2110C>G p.L704V | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (1); PolyPhen possibly damaging (0.452); catalogued as rs779032394, COSV100336781; called by muse, mutect2, varscan2
- CTPS1 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV101009456; called by muse, mutect2
- CUBN | c.7171G>C p.E2391Q | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.58); catalogued as COSV100913779, COSV64706832; called by muse, mutect2, varscan2
- CUL1 | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 67/87 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV57386998; called by muse, mutect2, varscan2
- CYP2A13 | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.207); catalogued as rs1048800592, COSV100387077; called by muse, mutect2, varscan2
- DCC | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as rs1420293884, COSV59142160; called by muse, mutect2, varscan2
- DCK | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.7); catalogued as COSV99709349; called by muse, mutect2, varscan2
- DDA1 | c.251C>G p.S84C | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.079); catalogued as COSV99345108; called by muse, mutect2
- DDX55 | c.371G>A p.G124E | Missense Mutation (SNP) | VAF 46/187 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1309098329, COSV53018051; called by muse, mutect2, varscan2
- DENND2B | c.2675C>G p.S892* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV100568001; called by muse, mutect2, varscan2
- DGAT2L6 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.676); catalogued as COSV100284206, COSV60719023; called by muse, mutect2, varscan2
- DIAPH2 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.926); catalogued as COSV100236169, COSV61268693; called by muse, mutect2, varscan2
- DIDO1 | c.2055-1G>C p.X685_splice | Splice Site (SNP) | VAF 11/44 reads (25%) | catalogued as COSV99827652; called by muse, mutect2, varscan2
- DISP2 | c.3812C>T p.P1271L | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as COSV99140767; called by muse, mutect2, varscan2
- DSCAM | c.3602C>T p.S1201L | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.393); catalogued as COSV101261823; called by muse, mutect2, varscan2
- DYNC2I1 | c.943G>C p.E315Q | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV101337757; called by muse, mutect2, varscan2
- ELMO2 | c.1629G>C p.Q543H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV99282168; called by muse, mutect2, varscan2
- EPHA8 | c.2448_2450del p.S817del | In Frame Del (DEL) | VAF 20/87 reads (23%) | catalogued as rs757340105; called by pindel, varscan2
- EPPK1 | c.3767C>T p.S1256F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs782130138, COSV101599995; called by muse, mutect2
- ERAP2 | c.2398C>T p.Q800* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs1284391366, COSV101163993; called by muse, mutect2, varscan2
- ETV1 | c.529G>T p.D177Y | Missense Mutation (SNP) | VAF 16/220 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV99624895; called by muse, mutect2
- EVC2 | c.2940G>C p.E980D | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV100187340; called by muse, mutect2, varscan2
- F9 | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 9/209 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as CM1311587, CM980721, COSV99497027; called by muse, mutect2
- FASTKD3 | c.175C>G p.H59D | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV99242239; called by muse, mutect2, varscan2
- FAT1 | c.10679C>G p.S3560* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as COSV71675330; called by muse, varscan2
- FAT1 | c.10570C>T p.Q3524* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV71673211, COSV71674468; called by muse, varscan2
- FCMR | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.024); catalogued as COSV100892940; called by muse, mutect2, varscan2
- FRAS1 | c.7085G>A p.R2362Q | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.219); catalogued as rs865839705, COSV53631054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FXR1 | c.1349C>T p.S450L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as COSV59762152; called by muse, mutect2, varscan2
- GABRE | c.1303G>C p.E435Q | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100944436; called by muse, mutect2, varscan2
- GARNL3 | c.1696G>C p.E566Q | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs763623214, COSV100150820; called by muse, mutect2, varscan2
- GBF1 | c.2158C>T p.Q720* (on ENST00000369983 / NM_001377137.1; = p.Q719* on NM_004193.3) | Nonsense Mutation (SNP) | VAF 17/62 reads (27%) | catalogued as COSV100890665, COSV100890742; called by muse, mutect2, varscan2
- GBGT1 | c.202C>T p.Q68* | Nonsense Mutation (SNP) | VAF 59/122 reads (48%) | catalogued as COSV100923181; called by muse, mutect2, varscan2
- GDPD5 | c.1604T>C p.L535P | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100409574; called by muse, mutect2, varscan2
- GOLGA6A | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.746); catalogued as COSV99297449; called by muse, mutect2, varscan2
- GRIA2 | c.592G>C p.D198H | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99646324; called by muse, mutect2, varscan2
- GTPBP4 | c.643C>G p.L215V | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as COSV100673000; called by muse, mutect2, varscan2
- HCAR1 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.055); catalogued as COSV63673052; called by muse, mutect2, varscan2
- HEATR5A | c.3191G>A p.R1064Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.084); catalogued as rs779508768, COSV101120756; called by muse, mutect2, varscan2
- HERC5 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV99988297; called by muse, mutect2, varscan2
- HLA-A | c.224G>A p.W75* | Nonsense Mutation (SNP) | VAF 4/32 reads (13%) | catalogued as rs41542016, CM099012, COSV65144284; called by mutect2, varscan2
- HLA-B | c.748C>G p.Q250E | Missense Mutation (SNP) | VAF 34/104 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.984); catalogued as COSV69522776, COSV69523296; called by muse, mutect2, varscan2
- HLA-B | c.171C>G p.F57L | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as rs41546213, COSV101318307; called by muse, mutect2, varscan2
- HOXA11 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as COSV99136168; called by muse, mutect2, varscan2
- HOXB5 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.077); catalogued as rs1453457823, COSV99494329; called by muse, mutect2, varscan2
- IFNA17 | c.527C>G p.S176C | Missense Mutation (SNP) | VAF 82/386 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.363); catalogued as COSV101303490; called by muse, mutect2, varscan2
- IFT88 | c.652G>T p.V218F (on ENST00000319980 / NM_001318493.2; = p.V209F on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV100179992, COSV60677250; called by muse, mutect2, varscan2
- IGFN1 | c.2774G>T p.G925V (on ENST00000295591 / NM_001367841.1; = p.G3382V on NM_001164586.2) | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99813816; called by muse, mutect2, varscan2
- IL7R | c.812T>A p.I271N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); catalogued as COSV100286810; called by muse, mutect2, varscan2
- IMPG1 | c.1712G>A p.R571Q | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as rs781353377, COSV64058960; called by muse, mutect2, varscan2
- INO80D | c.2702C>G p.S901C | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as COSV68959126; called by muse, mutect2, varscan2
- IPO11 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV57576397; called by muse, mutect2, varscan2
- KCNH7 | c.104G>A p.R35K | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.199); catalogued as rs867684583, COSV100038390; called by muse, mutect2, varscan2
- KIAA1217 | c.376C>T p.H126Y | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.434); catalogued as COSV100908549; called by muse, mutect2, varscan2
- KIAA1522 | c.2276C>T p.S759L (on ENST00000373480 / NM_001198972.2; = p.S818L on NM_020888.3) | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs749647280, COSV99615323; called by muse, mutect2, varscan2
- KIF24 | c.3004G>A p.D1002N | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs777128018, COSV99903628, COSV99903691; called by muse, mutect2, varscan2
- KIRREL2 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99384582; called by muse, mutect2, varscan2
- KLHL41 | c.55C>T p.L19F | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1283011570, COSV99500666; called by muse, mutect2, varscan2
- KNTC1 | c.6083C>G p.S2028* | Nonsense Mutation (SNP) | VAF 11/37 reads (30%) | catalogued as COSV100338943; called by muse, mutect2, varscan2
- KRT1 | c.888G>T p.M296I | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.866); catalogued as rs1294238409, COSV52865481; called by muse, mutect2, varscan2
- LAMA3 | c.343C>G p.P115A | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100557908; called by muse, mutect2, varscan2
- LRFN2 | c.2256G>C p.W752C | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100600092; called by muse, mutect2, varscan2
- LRRTM1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.79); PolyPhen benign (0.022); catalogued as rs1450163681, COSV54438730; called by muse, mutect2, varscan2
- LSR | c.86C>G p.P29R | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.078); catalogued as COSV100670694; called by muse, mutect2, varscan2
- MATN2 | c.520C>T p.Q174* | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV99646788; called by muse, mutect2, varscan2
- MCFD2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100109211; called by muse, mutect2, varscan2
- MCM7 | c.1490C>G p.P497R | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs759076249, COSV100385254; called by muse, mutect2, varscan2
- MDC1 | c.5533G>A p.D1845N | Missense Mutation (SNP) | VAF 62/222 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs780332704, COSV100903173; called by muse, mutect2, varscan2
- MST1R | c.3163G>A p.E1055K | Missense Mutation (SNP) | VAF 59/144 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.012); catalogued as rs751480532, COSV56566446, COSV99620032; called by muse, mutect2, varscan2
- MTFMT | c.269C>G p.S90* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV99584606; called by muse, mutect2, varscan2
- MTHFR | c.1700G>A p.R567Q | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.028); catalogued as rs750272108, COSV100453496; called by muse, mutect2, varscan2
- MTMR11 | c.980T>A p.L327Q (on ENST00000439741 / NM_001145862.2; = p.L255Q on NM_181873.3) | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as COSV100809385; called by muse, mutect2, varscan2
- MTMR11 | c.979C>A p.L327M (on ENST00000439741 / NM_001145862.2; = p.L255M on NM_181873.3) | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV100809387; called by muse, mutect2, varscan2
- MYBPC3 | c.3739G>A p.D1247N | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1255776478, COSV99921181; called by muse, mutect2, varscan2
- MYO15A | c.4520G>A p.R1507Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.151); catalogued as rs764263371, COSV99235013; called by muse, mutect2, varscan2
- N4BP2 | c.2734A>G p.I912V | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99789436; called by muse, mutect2, varscan2
- NCK1 | c.953C>G p.S318* | Nonsense Mutation (SNP) | VAF 4/44 reads (9%) | catalogued as COSV99999916; called by muse, mutect2
- NEB | c.6453G>A p.M2151I | Missense Mutation (SNP) | VAF 107/421 reads (25%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.899); catalogued as COSV99429321; called by muse, mutect2, varscan2
- NEIL2 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 30/79 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as COSV99462589; called by muse, mutect2, varscan2
- NFATC1 | c.1361C>T p.S454L | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.034); catalogued as rs376057065; called by muse, mutect2, varscan2
- NLRC5 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 81/172 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1205824043, COSV52663316; called by muse, mutect2, varscan2
- NOTCH1 | c.3951G>C p.K1317N | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as COSV99493061; called by muse, mutect2
- NPHS2 | c.310C>A p.L104I | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as COSV100858222; called by muse, mutect2, varscan2
- NUAK2 | c.216G>C p.E72D | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.084); catalogued as COSV100904186; called by muse, mutect2, varscan2
- NYAP1 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT tolerated (0.71); PolyPhen benign (0.08); catalogued as rs750370682, COSV55717978; called by muse, mutect2, varscan2
- OR10X1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 45/129 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs376239592; called by muse, mutect2, varscan2
- OR2T11 | c.886G>A p.G296R | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV100425008; called by muse, varscan2
- OR4S2 | c.565G>T p.E189* | Nonsense Mutation (SNP) | VAF 37/214 reads (17%) | catalogued as COSV100412873; called by muse, mutect2, varscan2
- P2RY10 | c.825C>A p.S275R | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV99409480; called by muse, mutect2, varscan2
- PCDH15 | c.4822G>A p.E1608K | Missense Mutation (SNP) | VAF 76/164 reads (46%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.063); catalogued as COSV57269929; called by muse, mutect2, varscan2
- PCDHGA10 | c.1801G>A p.D601N | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99549899; called by muse, mutect2, varscan2
- PCDHGA3 | c.826C>A p.Q276K | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.006); catalogued as COSV99549892; called by muse, mutect2, varscan2
- PHACTR1 | c.1144G>A p.E382K | Missense Mutation (SNP) | VAF 14/138 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.156); catalogued as COSV100279327, COSV60682441; called by muse, mutect2, varscan2
- PHYHIPL | c.105C>T p.D35= | Splice Region (SNP) | VAF 6/28 reads (21%) | catalogued as COSV65847812; called by muse, mutect2
- PLCG2 | c.2785G>A p.E929K | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as COSV63868628; called by muse, mutect2, varscan2
- PLEKHA4 | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99613499; called by muse, mutect2, varscan2
- PLEKHH1 | c.165G>C p.Q55H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100233572; called by muse, mutect2, varscan2
- PLPP7 | c.137C>G p.S46* | Nonsense Mutation (SNP) | VAF 9/33 reads (27%) | catalogued as COSV100952613, COSV64836150; called by muse, mutect2, varscan2
- POGLUT2 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99959222; called by muse, mutect2, varscan2
- POLQ | c.7321C>G p.Q2441E | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV99953238; called by muse, mutect2, varscan2
- PPP1R3D | c.416C>G p.S139W | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100674553, COSV100674720, COSV62564469; called by muse, mutect2, varscan2
- PRDM2 | c.4303C>T p.Q1435* | Nonsense Mutation (SNP) | VAF 64/205 reads (31%) | catalogued as COSV99341413; called by muse, mutect2, varscan2
- PRDM2 | c.4715C>G p.S1572C | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as COSV99343033; called by muse, varscan2
- PRKD1 | c.2693A>T p.E898V | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.203); catalogued as COSV100121879; called by muse, varscan2
- PRPF8 | c.1608G>C p.K536N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100518056; called by muse, mutect2, varscan2
- PSMG3 | c.191C>G p.T64R | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99365907; called by muse, mutect2, varscan2
- PTPN6 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100017352; called by muse, mutect2, varscan2
- RAB37 | c.601G>A p.E201K (on ENST00000392613 / NM_001006638.3; = p.E194K on NM_175738.5) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs745519873, COSV99380372; called by muse, varscan2
- RALGAPB | c.2782G>C p.E928Q | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99486026; called by muse, mutect2, varscan2
- RGS22 | c.2621C>T p.S874F | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.998); catalogued as COSV100693996; called by muse, mutect2, varscan2
- RNF13 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | catalogued as COSV100694342; called by muse, mutect2, varscan2
- RPN1 | c.993C>G p.I331M | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as COSV99957387; called by muse, mutect2, varscan2
- RPUSD3 | c.889C>T p.R297C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as rs377371328; called by mutect2, varscan2
- RRP15 | c.789C>A p.D263E | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV100860834; called by muse, mutect2, varscan2
- RYR1 | c.10630G>C p.D3544H | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV100617381; called by muse, mutect2, varscan2
- SATB2 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 26/83 reads (31%) | catalogued as COSV53483325, COSV99612930; called by muse, mutect2, varscan2
- SBF1 | c.177G>C p.E59D | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs1170645964, COSV100818156; called by muse, mutect2, varscan2
- SEPTIN2 | c.655G>A p.D219N | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV100765003; called by muse, mutect2, varscan2
- SERPINE3 | c.799G>C p.D267H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); catalogued as COSV101246612; called by muse, mutect2, varscan2
- SFN | c.741G>C p.Q247H | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.095); catalogued as COSV100212903; called by muse, mutect2
- SLC25A36 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); catalogued as COSV100149290; called by muse, mutect2, varscan2
- SLC25A43 | c.984C>A p.F328L | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as COSV99474866; called by muse, mutect2, varscan2
- SLC36A3 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.085); catalogued as COSV100077989, COSV58856720; called by muse, mutect2, varscan2
- SLC7A1 | c.1417G>A p.E473K | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.081); catalogued as COSV101060333; called by muse, mutect2, varscan2
- SMC2 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 17/137 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.061); catalogued as COSV99659964; called by muse, mutect2, varscan2
- SMTNL1 | c.220G>C p.D74H | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs753359199, COSV101216478, COSV101216616; called by muse, mutect2
- SNX17 | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as COSV99278162; called by muse, mutect2, varscan2
- SPANXN2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 191/633 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as COSV100979861, COSV65129955; called by muse, varscan2
- SPTBN1 | c.2413G>T p.E805* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | catalogued as COSV100443694, COSV61689618; called by muse, mutect2, varscan2
- SRFBP1 | c.109C>T p.R37* | Nonsense Mutation (SNP) | VAF 9/26 reads (35%) | catalogued as rs1370362238, COSV100233090, COSV59582748; called by muse, mutect2, varscan2
- SRSF7 | c.74G>C p.G25A | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.59); PolyPhen benign (0.18); catalogued as COSV100492839; called by muse, mutect2
- ST6GAL2 | c.357A>C p.K119N | Missense Mutation (SNP) | VAF 14/154 reads (9%) | PolyPhen benign (0.01); catalogued as COSV100868342; called by muse, mutect2
- SYAP1 | c.733C>T p.R245W | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs773957263, COSV101204984, COSV66468387; called by muse, mutect2, varscan2
- TANK | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV99376666; called by muse, mutect2, varscan2
- TBR1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.666); catalogued as rs1417056245, COSV101271576; called by muse, mutect2
- TEKT4 | c.537G>C p.K179N | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99726850; called by muse, mutect2, varscan2
- TESMIN | c.620C>A p.S207Y | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV99664098; called by muse, mutect2, varscan2
- TEX15 | c.6785G>A p.R2262K (on ENST00000256246; = p.R2645K on NM_001350162.2) | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV104373305, COSV99822414; called by muse, mutect2, varscan2
- TNIK | c.2573G>C p.S858T | Missense Mutation (SNP) | VAF 123/400 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as COSV99460549; called by muse, mutect2, varscan2
- TRIO | c.3541G>C p.E1181Q | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs773995062, COSV100711169; called by muse, mutect2, varscan2
- TRMT13 | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as rs147022991; called by muse, mutect2, varscan2
- TXNRD2 | c.1480G>A p.V494M | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs762203465, COSV101266323; called by muse, mutect2, varscan2
- UBE2Q1 | c.1080G>C p.W360C | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV52724433, COSV99427772; called by muse, mutect2, varscan2
- UGT2B17 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 80/314 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.873); catalogued as COSV100497337; called by muse, mutect2, varscan2
- WDR7 | c.3203C>G p.S1068* | Nonsense Mutation (SNP) | VAF 13/35 reads (37%) | catalogued as COSV99590799; called by muse, mutect2, varscan2
- WDR90 | c.4018G>A p.D1340N | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99554376; called by muse, mutect2, varscan2
- XKRX | c.1107C>G p.F369L | Missense Mutation (SNP) | VAF 50/168 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100139869, COSV60708515; called by muse, mutect2, varscan2
- XPR1 | c.52C>G p.Q18E | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as COSV100851539; called by muse, varscan2
- ZFHX3 | c.1486C>T p.P496S | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51735777; called by muse, mutect2, varscan2
- ZFP14 | c.59G>A p.W20* | Nonsense Mutation (SNP) | VAF 6/66 reads (9%) | catalogued as COSV99525397; called by muse, mutect2
- ZIC3 | c.1304C>A p.S435Y | Missense Mutation (SNP) | VAF 86/240 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV54977037, COSV99799687; called by muse, mutect2, varscan2
- ZNF155 | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV99525848; called by muse, mutect2, varscan2
- ZNF335 | c.3718G>A p.E1240K | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV100533561; called by muse, mutect2, varscan2
- ZNF415 | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 22/67 reads (33%) | catalogued as COSV99701855, COSV99702169; called by muse, mutect2, varscan2
- ZNF503 | c.1768C>G p.R590G | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100998053; called by muse, mutect2
- ZNF582 | c.530G>C p.R177T | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.099); catalogued as COSV100019065; called by muse, mutect2, varscan2
- ZNF836 | c.1414T>C p.C472R | Missense Mutation (SNP) | VAF 11/149 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100441415; called by muse, mutect2
- ZSWIM5 | c.2651G>A p.R884H | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs768308725, COSV99869794; called by muse, mutect2, varscan2
- B2M | c.79dup p.I27Nfs*30 | Frame Shift Ins (INS) | VAF 26/111 reads (23%) | called by mutect2, pindel, varscan2
- BOP1 | c.349C>T p.R117W | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCN2 | c.47_60del p.Q16Pfs*27 | Frame Shift Del (DEL) | VAF 12/67 reads (18%) | called by mutect2, pindel, varscan2
- DDX21 | c.1859del p.G620Vfs*5 | Frame Shift Del (DEL) | VAF 67/167 reads (40%) | called by mutect2, pindel, varscan2
- DOCK11 | c.1191dup p.I398Yfs*7 | Frame Shift Ins (INS) | VAF 45/178 reads (25%) | called by mutect2, pindel, varscan2
- EIF2AK4 | c.3088_3103del p.M1030Sfs*18 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- ERCC6L2 | c.4132G>C p.D1378H | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- FOSL2 | c.606_609dup p.P204Sfs*56 | Frame Shift Ins (INS) | VAF 13/77 reads (17%) | called by mutect2, pindel, varscan2
- GSAP | c.2253C>G p.I751M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- NAP1L3 | c.529del p.V177Cfs*12 | Frame Shift Del (DEL) | VAF 24/99 reads (24%) | called by mutect2, pindel, varscan2
- PISD | c.955_958del p.T319Lfs*36 (on ENST00000439502 / NM_001326412.1; = p.T285Lfs*36 on NM_014338.3) | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel*, varscan2*
- RCSD1 | c.1010_1013del p.K337Sfs*8 | Frame Shift Del (DEL) | VAF 5/15 reads (33%) | called by mutect2, varscan2
- SUPT20HL1 | c.310C>T p.R104W | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ACSS1 | c.624C>T p.I208= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs1387415511, COSV100054189; called by muse, mutect2, varscan2
- ACTL6B | c.243C>T p.V81= | Silent (SNP) | VAF 32/117 reads (27%) | catalogued as rs1390540444, COSV50521300; called by muse, mutect2, varscan2
- ADGRA2 | c.2265G>C p.L755= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV55104936; called by muse, mutect2, varscan2
- AKAP4 | c.714G>A p.E238= | Silent (SNP) | VAF 31/124 reads (25%) | catalogued as COSV100654397; called by muse, mutect2, varscan2
- ATP1A4 | c.3042C>T p.L1014= | Silent (SNP) | VAF 40/168 reads (24%) | catalogued as COSV100927236; called by muse, varscan2
- ATP2B3 | c.3363C>T p.F1121= (on ENST00000263519 / NM_001001344.2; = p.P1173S on NM_021949.3) | Silent (SNP) | VAF 54/133 reads (41%) | catalogued as COSV99686303; called by muse, mutect2, varscan2
- BIRC6 | c.3987G>A p.E1329= | Silent (SNP) | VAF 15/80 reads (19%) | catalogued as COSV101429373; called by muse, mutect2, varscan2
- BMERB1 | c.300C>T p.I100= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV100253597; called by muse, mutect2, varscan2
- CHD4 | c.1128C>A p.P376= (on ENST00000357008 / NM_001363606.2; = p.P389= on NM_001273.5) | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as COSV100539580; called by muse, mutect2, varscan2
- CLUH | c.519G>A p.R173= (on ENST00000435359; = p.R211= on NM_015229.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs751501308; called by muse, varscan2
- CNTN4 | c.144C>G p.L48= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as rs753979733, COSV101281811; called by muse, mutect2
- COL16A1 | c.3228G>A p.L1076= | Silent (SNP) | VAF 28/70 reads (40%) | catalogued as COSV99595865; called by muse, mutect2, varscan2
- CUL1 | c.57G>A p.Q19= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as COSV100297008; called by muse, mutect2, varscan2
- DNAJC5B | c.348C>T p.I116= | Silent (SNP) | VAF 26/86 reads (30%) | catalogued as rs377233329, COSV99395919; called by muse, mutect2, varscan2
- DSP | c.8538G>A p.R2846= | Silent (SNP) | VAF 42/170 reads (25%) | catalogued as COSV100673080; called by muse, mutect2, varscan2
- EHMT1 | c.3564C>T p.D1188= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as rs751507253, COSV66044949; called by muse, mutect2, varscan2
- EPS8L2 | c.822G>A p.Q274= | Silent (SNP) | VAF 32/92 reads (35%) | catalogued as COSV59346785, COSV59348887; called by muse, varscan2
- ERBB3 | c.129G>A p.E43= | Silent (SNP) | VAF 53/200 reads (27%) | catalogued as COSV57259057; called by muse, mutect2, varscan2
- ERCC4 | c.228G>A p.L76= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs61760162; ClinVar: uncertain significance / likely benign; called by mutect2, varscan2
- FGFR4 | c.2055C>T p.L685= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs1374624570, COSV52801369; called by muse, mutect2, varscan2
- GBP1 | c.1329G>A p.L443= | Silent (SNP) | VAF 81/289 reads (28%) | catalogued as COSV100976319; called by muse, mutect2, varscan2
- H2BC3 | c.84G>A p.K28= | Silent (SNP) | VAF 47/182 reads (26%) | catalogued as rs1014522036, COSV100778234, COSV100778329; called by muse, mutect2, varscan2
- H3C11 | c.168G>A p.Q56= | Silent (SNP) | VAF 41/116 reads (35%) | catalogued as rs1265480179, COSV100138152, COSV58899726; called by muse, mutect2, varscan2
- HCFC2 | c.339G>C p.V113= | Silent (SNP) | VAF 58/191 reads (30%) | catalogued as COSV99983389; called by muse, mutect2, varscan2
- IKZF1 | c.900G>A p.E300= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV58782752; called by muse, mutect2
- IL36B | c.432C>T p.L144= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as COSV99383098, COSV99383296; called by muse, mutect2, varscan2
- KARS1 | c.969G>A p.R323= | Silent (SNP) | VAF 81/193 reads (42%) | catalogued as COSV100094677; called by muse, mutect2, varscan2
- KIF3C | c.357C>G p.V119= | Silent (SNP) | VAF 26/92 reads (28%) | catalogued as COSV99268051; called by muse, mutect2, varscan2
- KLHL2 | c.441A>G p.E147= | Silent (SNP) | VAF 35/99 reads (35%) | catalogued as COSV99900564; called by muse, mutect2, varscan2
- KNDC1 | c.3054G>A p.S1018= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs191568937; called by muse, varscan2
- KNDC1 | c.3174C>T p.G1058= | Silent (SNP) | VAF 11/47 reads (23%) | catalogued as rs1409403314, COSV58833496; called by muse, varscan2
- KRTAP10-10 | c.162G>A p.Q54= | Silent (SNP) | VAF 35/105 reads (33%) | catalogued as COSV59956827; called by muse, mutect2, varscan2
- LCOR | c.492G>A p.L164= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as COSV100603990; called by muse, mutect2, varscan2
- LGMN | c.27C>T p.L9= | Silent (SNP) | VAF 22/87 reads (25%) | catalogued as COSV100606056; called by muse, mutect2, varscan2
- LRRIQ1 | c.138A>G p.S46= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs1187615499, COSV101277754; called by muse, mutect2, varscan2
- LTK | c.315G>A p.L105= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs767961282, COSV55490858; called by muse, varscan2
- MECOM | c.1293C>T p.F431= (on ENST00000468789 / NM_001105078.4; = p.F619= on NM_004991.4) | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as COSV99244222, COSV99245896; called by muse, mutect2, varscan2
- MED12L | c.243G>A p.L81= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV56375528; called by muse, mutect2, varscan2
- MPST | c.360C>T p.F120= (on ENST00000341116 / NM_001369904.2; = p.F140= on NM_021126.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/17 reads (41%) | catalogued as rs1294670493, COSV100353485; called by muse, mutect2, varscan2
- MYH2 | c.1275C>T p.N425= | Silent (SNP) | VAF 19/141 reads (13%) | catalogued as rs151000841; ClinVar: likely benign; called by muse, mutect2, varscan2
- NDOR1 | c.948C>T p.L316= | Silent (SNP) | VAF 69/120 reads (58%) | catalogued as COSV61288098; called by muse, mutect2, varscan2
- OLIG3 | c.285G>A p.R95= | Silent (SNP) | VAF 36/98 reads (37%) | catalogued as COSV100880359; called by muse, mutect2, varscan2
- OR2T27 | c.189C>T p.L63= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs567610961, COSV100788396; called by mutect2, varscan2
- OSBP | c.481C>T p.L161= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV99802792; called by muse, mutect2, varscan2
- PKD2L1 | c.1431C>T p.I477= | Silent (SNP) | VAF 33/130 reads (25%) | catalogued as rs779515700, COSV100559483; called by muse, mutect2, varscan2
- PLXNA2 | c.2289G>A p.Q763= | Silent (SNP) | VAF 20/70 reads (29%) | catalogued as COSV100886199; called by muse, mutect2, varscan2
- POLR1G | c.60G>A p.A20= | Silent (SNP) | VAF 32/119 reads (27%) | catalogued as COSV100338390; called by muse, mutect2, varscan2
- PRKAG2 | c.1383T>A p.P461= | Silent (SNP) | VAF 25/102 reads (25%) | catalogued as COSV99836373; called by muse, mutect2, varscan2
- PROKR1 | c.903C>T p.Y301= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs374654942; called by muse, mutect2, varscan2
- PRPF8 | c.1368G>C p.L456= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV100518057, COSV59267907; called by muse, mutect2, varscan2
- PSD4 | c.936C>T p.I312= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99831576; called by muse, mutect2, varscan2
- RAET1E | c.588C>T p.F196= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100593559; called by muse, mutect2
- RALGAPA2 | c.5451C>T p.N1817= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs778013504, COSV52494709; called by muse, mutect2, varscan2
- S1PR4 | c.528G>A p.L176= | Silent (SNP) | VAF 14/164 reads (9%) | catalogued as COSV99859521; called by muse, mutect2
- SAGE1 | c.888C>T p.V296= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV100186476, COSV100188121; called by muse, mutect2
- SAGE1 | c.1476G>A p.K492= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as rs1226717861, COSV100188123; called by muse, mutect2, varscan2
- SEPTIN6 | c.1188C>T p.F396= | Silent (SNP) | VAF 74/181 reads (41%) | catalogued as COSV100595921; called by muse, mutect2, varscan2
- SERPINH1 | c.426C>T p.F142= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs371660937; called by muse, mutect2
- SIGMAR1 | c.570C>A p.V190= | Silent (SNP) | VAF 14/69 reads (20%) | catalogued as COSV99449454, COSV99449627; called by muse, mutect2, varscan2
- SLC27A1 | c.1860C>T p.F620= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as COSV99393607; called by muse, mutect2, varscan2
- SLC6A3 | c.1494C>T p.F498= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV99549032; called by muse, mutect2, varscan2
- SLX4 | c.4455G>A p.Q1485= | Silent (SNP) | VAF 75/229 reads (33%) | catalogued as COSV99568874; called by muse, mutect2, varscan2
- SMAP1 | c.162C>T p.I54= | Silent (SNP) | VAF 15/75 reads (20%) | catalogued as rs1296315890, COSV57642940; called by muse, mutect2, varscan2
- SOX1 | c.240G>A p.E80= | Silent (SNP) | VAF 23/47 reads (49%) | catalogued as rs780331342, COSV100447203; called by muse, mutect2, varscan2
- SP6 | c.852C>T p.F284= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV100647116; called by muse, mutect2, varscan2
- STK10 | c.549G>C p.L183= | Silent (SNP) | VAF 8/43 reads (19%) | catalogued as COSV99452539; called by muse, mutect2, varscan2
- SYT9 | c.810A>G p.T270= | Silent (SNP) | VAF 10/206 reads (5%) | catalogued as COSV100609580; called by muse, mutect2
- TAS2R14 | c.438A>G p.A146= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV101115985; called by muse, mutect2, varscan2
- TEX29 | c.438C>T p.A146= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs985076336, COSV99366250; called by muse, mutect2, varscan2
- THRSP | c.141C>G p.G47= | Silent (SNP) | VAF 21/131 reads (16%) | catalogued as COSV99806588; called by muse, mutect2, varscan2
- TMEM37 | c.447C>G p.L149= | Silent (SNP) | VAF 86/313 reads (27%) | catalogued as COSV99191789; called by muse, mutect2, varscan2
- TPRA1 | c.619C>T p.L207= | Silent (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99952498; called by muse, mutect2, varscan2
- UNC79 | c.4185G>A p.R1395= (on ENST00000393151 / NM_001346218.2; = p.R1218= on NM_020818.5) | Silent (SNP) | VAF 9/110 reads (8%) | catalogued as rs1208044802, COSV99830309; called by muse, mutect2
- WAPL | c.69C>G p.V23= | Silent (SNP) | VAF 4/56 reads (7%) | catalogued as COSV100077410; called by muse, mutect2
- WASF1 | c.1224G>A p.E408= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as COSV100847002; called by muse, mutect2, varscan2
- ZNF584 | c.561C>T p.F187= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as rs1321416545, COSV100183477; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73824603 G>C | 5'Flank (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- LRP5L | n.286C>G | RNA (SNP) | VAF 18/101 reads (18%) | catalogued as COSV101292848; called by muse, mutect2, varscan2
